Somatic mutation profile of tumor specimen TCGA-VP-A87K-01A (aliquot TCGA-VP-A87K-01A-11D-A34U-08) from TCGA case TCGA-VP-A87K, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.1 years (23,030 days).
Specimen TCGA-VP-A87K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27c57489-6fb8-47b2-beff-364344767d8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VP-A87K-10A (Blood Derived Normal), aliquot TCGA-VP-A87K-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d17683c0-9391-41a7-bb6f-2021f48e47e8

The open-access MAF lists 29 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 19, Silent 5, Nonsense Mutation 3, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BPIFA1 | c.167G>A p.S56N | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.205); catalogued as rs375396851; called by muse, mutect2, varscan2
- CA4 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs777463944, COSV56281014; called by muse, mutect2, varscan2
- CDK20 | c.563+1G>C p.X188_splice | Splice Site (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100308203; called by muse, mutect2, varscan2
- CSMD3 | c.3861T>G p.H1287Q (on ENST00000297405 / NM_001363185.1; = p.H1183Q on NM_052900.3) | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV99843994; called by muse, mutect2, varscan2
- ENKD1 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 9/127 reads (7%) | catalogued as COSV99537946; called by muse, mutect2
- GLDN | c.1357G>C p.D453H | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100117995; called by muse, mutect2, varscan2
- KCND2 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.523); catalogued as rs1044289793, COSV100474141, COSV58569920; called by muse, mutect2, varscan2
- KIAA2026 | c.400G>T p.G134* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV99424332; called by muse, mutect2, varscan2
- MAD2L1 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs773286573, COSV99633932; called by muse, varscan2
- MCM8 | c.1745C>A p.A582E | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV99496100; called by muse, mutect2
- MRTFB | c.3247A>G p.M1083V (on ENST00000571589 / NM_001365412.2; = p.M1033V on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs763639553, COSV100371687; called by muse, mutect2, varscan2
- PCNT | c.7457C>T p.S2486F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs758636838, COSV100855922; called by muse, mutect2, varscan2
- PGK2 | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 20/140 reads (14%) | catalogued as rs1450469250, COSV100505641; called by muse, mutect2, varscan2
- PIK3CD | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV63128987; called by muse, mutect2
- SEC63 | c.1601A>C p.K534T | Missense Mutation (SNP) | VAF 75/163 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.288); catalogued as COSV100938452; called by muse, mutect2, varscan2
- SEL1L3 | c.2242C>G p.R748G | Missense Mutation (SNP) | VAF 103/259 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as COSV99341026; called by muse, mutect2, varscan2
- SPEG | c.9683G>A p.R3228H | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1291052959, COSV56663233; called by muse, mutect2
- STAT4 | c.1899G>T p.L633F | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100636140; called by muse, mutect2, varscan2
- TRANK1 | c.8254G>A p.E2752K | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV57147380, COSV57152147; called by muse, mutect2, varscan2
- TULP2 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs1352515660, COSV99618082; called by muse, mutect2
- UBE3B | c.1835C>G p.P612R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV99784356; called by muse, varscan2
- ZAP70 | c.1817G>A p.G606E | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.015); catalogued as COSV99385854; called by muse, mutect2, varscan2
- ZBTB46 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV99829594; called by muse, mutect2, varscan2
- OTOP3 | c.910del p.H304Tfs*65 | Frame Shift Del (DEL) | VAF 94/222 reads (42%) | called by mutect2, varscan2
- ABCA13 | c.4881T>C p.A1627= | Silent (SNP) | VAF 69/155 reads (45%) | catalogued as COSV101330148; called by muse, mutect2, varscan2
- EDNRA | c.603A>G p.V201= | Silent (SNP) | VAF 55/153 reads (36%) | catalogued as COSV100163582, COSV60100864; called by muse, mutect2, varscan2
- OR1C1 | c.375G>A p.A125= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as rs1045359996, COSV101376298, COSV68715720; called by muse, mutect2, varscan2
- PALD1 | c.504G>A p.V168= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV99698565; called by muse, mutect2, varscan2
- XIRP2 | c.102T>A p.G34= (on ENST00000628543; = p.G209= on NM_152381.6) | Silent (SNP) | VAF 61/125 reads (49%) | catalogued as COSV99746281; called by muse, mutect2, varscan2
